Gene-level copy-number profile of tumor specimen C3N-01074-01 from CPTAC case C3N-01074, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 57.0 years (20,803 days).
Specimen C3N-01074-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cdcd01ae-e310-42fe-bce2-85ad4a486fe1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01074-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/9c5efc2d-9af7-4e3d-af28-8bc97e866628

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 20,521; copy number 2: 29,720; copy number 3: 6,718; copy number 4: 586; copy number 5: 707; copy number 6: 65; copy number 7: 67; copy number 8: 73; copy number 9: 207; copy number 10: 151; copy number 14: 50; copy number 16: 31; copy number 17: 6.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,357 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:80,351,132–81,842,866, 46 genes, copy number 10–16: AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, PAG1, AC022778.1, AC079209.2, AC079209.1, AC009902.1, UBE2HP1, AC009902.3, AC009902.2, FABP5, AC018616.1, PMP2, FABP9, FABP4, AC023644.1, FTH1P11, FABP12, IMPA1P1, NIPA2P4, RPS26P34, SLC10A5P1, IMPA1, SLC10A5, AC132219.2, ZFAND1, CHMP4C, AC132219.1, SNX16, HNRNPA1P36.
- chr8:85,744,543–89,757,812, 45 genes, copy number 8–9 (within-gene range 3–9): REXO1L10P, REXO1L9P, REXO1L2P, AC232323.1, REXO1L4P, REXO1L5P, REXO1L6P, AC100801.1, LINC02849, ATP6V0D2, AC023194.1, AC023194.2, PSKH2, AC023194.3, AC084128.1, SLC7A13, AC103760.1, WWP1, RMDN1, NTAN1P2, SLC2A3P4, CPNE3, CNGB3, MIOXP1, GOLGA2P1, UBE2Q2P10, AC090572.3, AC090572.2, AC090572.1, CNBD1, AF121898.1, VTA1P2, IARS2P1, SOX5P1, AC005066.1, DCAF4L2, AC037450.1, MMP16, AC090578.1, RNA5SP272, AC090568.1, AC090578.2, RPSAP74, KRT8P4, AF117829.1.
- chr8:91,542,924–91,907,619, 1 gene, copy number 10 (within-gene range 3–10): AC103409.1.
- chr8:91,909,738–93,744,534, 31 genes, copy number 10: PRR13P7, MRPS16P1, RUNX1T1, AF181450.1, AC104339.1, AC022695.1, AC022695.2, AC022695.3, AC091096.1, AC104211.1, FLJ46284, AC104211.2, AC117834.2, AC117834.1, TRIQK, IRF5P1, MIR8084, C8orf87, LINC00535, AC016885.1, AC016885.3, AC016885.2, RNA5SP274, ZNF317P1, CIBAR1, AC120053.1, AC010834.3, RBM12B, AC010834.1, RBM12B-AS1, AC010834.2.
- chr8:109,362,461–113,436,939, 28 genes, copy number 10–17 (within-gene range 4–17): PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053.
- chr8:113,432,224–113,433,129, 1 gene, copy number 10: AC055788.2.
- chr8:114,791,653–114,791,929, 1 gene, copy number 10: CARS1P2.
- chr8:119,557,086–127,419,050, 123 genes, copy number 9–14 (within-gene range 4–14) (broad region; genes not listed).
- chr8:127,072,694–127,742,951, 10 genes, copy number 10: CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC.
- chr8:129,241,228–129,291,275, 3 genes, copy number 10: AC103833.2, AC103833.1, RN7SKP206.
- chr8:129,728,744–129,786,624, 2 genes, copy number 16: MTRF1LP2, GSDMC.
- chr12:66,767–34,249,958, 828 genes, copy number 5–9 (within-gene range 5–10) (broad region; genes not listed).
- chr14:28,264,390–31,026,401, 46 genes, copy number 5 (within-gene range 1–5): BNIP3P1, AL139023.1, RPL26P3, LINC02300, EIF4A1P12, BTF3P2, FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282, LINC02281, LINC02327, AL122126.1, LINC02326, Y_RNA, AL135878.1, RNU6-864P, AL133166.1, AL158058.1, AL158058.2, RNU11-5P, PRKD1, AL356756.1, RNU6-1234P, AL355053.1, AL133372.3, AL133372.2, AL133372.1, AL079305.1, G2E3-AS1, AL117355.1, SYF2P1, G2E3, SCFD1, UBE2CP1, AL121852.1, RPL12P5, AL049830.2, AL049830.1, COCH, AL049830.3, STRN3, HIGD1AP17, MIR624, AL049830.4.
- chr14:31,244,761–33,804,176, 34 genes, copy number 5–9: Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2, AL139353.1, AL139353.2, DTD2, AL163973.1, GPR33, NUBPL, AL163973.3, AL163973.2, RNU6-602P, RNU6-455P, AL355112.1, LINC02313, AL352984.2, AL352984.1, ARHGAP5-AS1, ARHGAP5, AL161665.1, RNU6-7, RNU6-8, AL136298.2, KIAA1143P1, AKAP6, AL136298.1, RN7SL660P, MTCO1P2, AL049781.1, NPAS3, AL161851.1, AL161851.2.
- chr14:43,990,539–44,386,064, 1 gene, copy number 5 (within-gene range 4–5): LINC02307.
- chr14:44,290,997–52,791,668, 155 genes, copy number 5–8 (broad region; genes not listed).
- chr14:52,792,875–52,820,034, 2 genes, copy number 8: AL139317.1, AL139317.2.

Autosomal genes at a single copy (total copy number 1): 17,670. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
